Somatic mutation profile of tumor specimen MMRF_2445_1_BM_CD138pos (aliquot MMRF_2445_1_BM_CD138pos_T1_KHS5U_L11607) from MMRF case MMRF_2445, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.0 years (23,750 days).
Specimen MMRF_2445_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c26442b8-f911-4d40-9642-caaace40095b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2445_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2445_1_PB_Whole_C3_KHS5U_L11608; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c321b60a-dd14-4fa0-8586-9320328a5022

The open-access MAF lists 186 somatic variants for this specimen: 74 protein-altering or splice-affecting, 24 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, 3'UTR 43, Intron 26, Silent 24, RNA 7, 5'UTR 6, Frame Shift Del 5, Splice Site 3, 5'Flank 3, 3'Flank 3, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1M1 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 27/412 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs771009421, COSV52228639; called by muse, mutect2
- ARMC3 | c.2095G>T p.V699F | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1007251587; called by muse, mutect2, varscan2
- CAPN5 | c.1616G>A p.R539H (on ENST00000456580; = p.R499H on NM_004055.5) | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs140490506; called by muse, mutect2, varscan2
- CD22 | c.677G>C p.G226A | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.043); catalogued as COSV50063457; called by muse, mutect2, varscan2
- CHRNB2 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100872508; called by muse, mutect2, varscan2
- EHD2 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 107/623 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as rs751209627, COSV54408023; called by muse, mutect2, varscan2
- IGLV3-1 | c.204A>T p.Q68H | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs376783127; called by muse, varscan2
- IGLV3-1 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 112/191 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs373029284; called by muse, varscan2
- KDR | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT tolerated (0.57); PolyPhen benign (0.087); catalogued as rs145458680, COSV55763284; called by muse, mutect2, varscan2
- MALRD1 | c.4539T>G p.D1513E | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65983513; called by muse, mutect2
- MPDZ | c.3842C>T p.A1281V | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1200591851; called by muse, mutect2, varscan2
- MYO16 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV51789994; called by muse, mutect2, varscan2
- PACRG | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV61306411; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.331G>A p.A111T (on ENST00000259318 / NM_001136562.3; = p.A342T on NM_007203.5) | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV99395483; called by muse, mutect2, varscan2
- PHTF1 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs761291402; called by muse, mutect2, varscan2
- PLEK | c.394T>A p.S132T | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52253342; called by muse, mutect2
- PTPRN2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1047290785, COSV67026880; called by muse, mutect2
- PYROXD2 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs1247471618; called by muse, mutect2, varscan2
- SETD5 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CD164748; called by muse, mutect2, varscan2
- SIGLEC8 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 118/536 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs1481646465; called by muse, mutect2, varscan2
- SLC27A6 | c.1150A>G p.N384D | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs989832083; called by muse, mutect2, varscan2
- TTN | c.31094A>T p.E10365V (on ENST00000591111; = p.E9438V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/214 reads (7%) | PolyPhen benign (0.161); catalogued as COSV100601626; called by muse, mutect2
- ULK3 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs200157375; called by mutect2, varscan2
- XKR7 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV73813397; called by muse, mutect2, varscan2
- ZNF616 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs774053561; called by muse, mutect2, varscan2
- ZNF843 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV59848719; called by muse, mutect2, varscan2
- ACP7 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ALPK1 | c.2405T>G p.F802C | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.258); called by muse, mutect2
- ANXA10 | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- APOE | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C20orf194 | c.2649A>C p.Q883H | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2
- CBX8 | c.246A>C p.K82N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNTNAP2 | c.1049T>A p.L350H | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- COLGALT1 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CSMD3 | c.3143T>A p.L1048H (on ENST00000297405 / NM_001363185.1; = p.L944H on NM_052900.3) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CSRNP3 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.714); called by muse, mutect2
- CTDSPL | c.379A>T p.N127Y (on ENST00000273179 / NM_001008392.2; = p.N116Y on NM_005808.3) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EFCAB5 | c.2413G>T p.G805C | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- EPHA4 | c.1263del p.K421Nfs*14 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- FAM131B | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 114/648 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- FNBP1L | c.1651+1G>A p.X551_splice (on ENST00000271234 / NM_001164473.2; = p.X493_splice on NM_017737.5) | Splice Site (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- GJD3 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.42); called by muse, varscan2
- GRM7 | c.735A>G p.A245= | Splice Region (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- IGHJ6 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 20/50 reads (40%) | PolyPhen probably damaging (0.996); called by muse, varscan2
- KCNA3 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2
- LAMA5 | c.3887del p.L1296Rfs*59 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- LRP3 | c.1115A>G p.E372G | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- LRP8 | c.1373A>T p.E458V | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MFAP3L | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC17 | c.10031A>T p.N3344I | Missense Mutation (SNP) | VAF 56/1056 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.645); called by muse, mutect2
- MYBBP1A | c.2904C>G p.C968W | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- NFU1 | c.564T>G p.D188E (on ENST00000410022 / NM_001002755.4; = p.D164E on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPC1L1 | c.2914T>A p.S972T | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR1 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- OR13C8 | c.944del p.N315Tfs*? | Frame Shift Del (DEL) | VAF 84/441 reads (19%) | called by pindel, varscan2
- OSBPL7 | c.2347A>G p.I783V | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PHF20L1 | c.1738C>G p.Q580E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- PNPLA6 | c.2803C>T p.R935C (on ENST00000414982 / NM_001166111.2; = p.R887C on NM_006702.5) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PSEN1 | c.804del p.R269Vfs*28 | Frame Shift Del (DEL) | VAF 13/119 reads (11%) | called by mutect2, pindel, varscan2
- PSMG1 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- RASGRF2 | c.457A>T p.I153F | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2
- RFPL1 | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 39/335 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); called by muse, varscan2
- ROBO2 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- SCPEP1 | c.1345A>T p.T449S | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- SDK2 | c.368G>C p.S123T | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC12A2 | c.2978-2A>C p.X993_splice | Splice Site (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- SLC24A1 | c.215T>C p.M72T | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- SMCHD1 | c.2665dup p.T889Nfs*15 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- SPATA31E1 | c.3823C>T p.H1275Y | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2
- THSD7B | c.2056A>C p.I686L | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.031); called by muse, mutect2
- TOP1 | c.155+2T>A p.X52_splice | Splice Site (SNP) | VAF 42/201 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.11266del p.T3756Rfs*3 (on ENST00000591111; = p.T3710Rfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 38/159 reads (24%) | called by mutect2, pindel, varscan2
- UBXN6 | c.662T>G p.I221S | Missense Mutation (SNP) | VAF 161/413 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- VSIG10 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ANKRD17 | c.1488C>T p.V496= | Silent (SNP) | VAF 36/255 reads (14%) | called by muse, mutect2, varscan2
- BMP6 | c.1509G>A p.R503= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as rs866183200, COSV99307251; called by muse, mutect2
- CBL | c.1779G>T p.R593= | Silent (SNP) | VAF 23/369 reads (6%) | called by muse, mutect2
- CTDSPL | c.381T>C p.N127= (on ENST00000273179 / NM_001008392.2; = p.N116= on NM_005808.3) | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs751687840; called by muse, mutect2
- CYP4F22 | c.1116G>A p.R372= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs1022666788; called by muse, mutect2, varscan2
- DZIP1L | c.276C>T p.L92= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- FBXL2 | c.549C>T p.G183= | Silent (SNP) | VAF 52/169 reads (31%) | called by muse, mutect2, varscan2
- KCND3 | c.597C>A p.T199= | Silent (SNP) | VAF 72/230 reads (31%) | called by muse, mutect2, varscan2
- KEL | c.1986G>T p.L662= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs140592001, COSV62335591; called by muse, mutect2, varscan2
- KSR2 | c.2073C>A p.I691= | Silent (SNP) | VAF 17/219 reads (8%) | called by muse, mutect2
- LRRTM3 | c.1470C>T p.T490= | Silent (SNP) | VAF 8/204 reads (4%) | catalogued as COSV100791464; called by muse, mutect2
- NRXN1 | c.552T>A p.I184= | Silent (SNP) | VAF 21/377 reads (6%) | called by muse, mutect2
- PCDHB3 | c.951C>T p.V317= | Silent (SNP) | VAF 10/272 reads (4%) | called by muse, mutect2
- PPP1R37 | c.1734C>T p.P578= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs1040455794; called by muse, mutect2, varscan2
- PRELID3A | c.411T>G p.L137= | Silent (SNP) | VAF 83/250 reads (33%) | called by muse, mutect2, varscan2
- PRKCG | c.903G>A p.K301= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as rs1487264720; called by muse, mutect2, varscan2
- PROM2 | c.198C>T p.T66= | Silent (SNP) | VAF 66/243 reads (27%) | catalogued as rs140148451; called by muse, mutect2, varscan2
- PRR23A | c.714G>A p.P238= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs753362710; called by muse, mutect2, varscan2
- RETREG1 | c.231G>C p.L77= | Silent (SNP) | VAF 16/114 reads (14%) | called by mutect2, varscan2
- SIK3 | c.504A>T p.T168= (on ENST00000445177 / NM_001366686.2; = p.T174= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 104/388 reads (27%) | called by muse, mutect2, varscan2
- TALDO1 | c.138G>A p.P46= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs11550601, COSV59798666; called by muse, mutect2, varscan2
- TDRD1 | c.3141G>T p.A1047= | Silent (SNP) | VAF 67/163 reads (41%) | called by muse, mutect2, varscan2
- TEAD2 | c.222C>T p.G74= | Silent (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2
- ZNF454 | c.474T>A p.T158= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- AC079612.1 | n.2744C>T | RNA (SNP) | VAF 13/188 reads (7%) | catalogued as rs944067764; called by muse, mutect2
- ADI1 | c.420+105G>A | Intron (SNP) | VAF 79/121 reads (65%) | catalogued as rs913990457; called by muse, mutect2, varscan2
- ALG14 | c.*123A>G | 3'UTR (SNP) | VAF 5/83 reads (6%) | catalogued as rs1472453960; called by muse, mutect2
- ANKRD37 | c.180+17T>G | Intron (SNP) | VAF 43/97 reads (44%) | catalogued as rs878996856; called by muse, mutect2, varscan2
- AP001007.2 | n.268G>A | RNA (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- AP002748.5 | c.*298G>T | 3'UTR (SNP) | VAF 63/251 reads (25%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.*44C>T | 3'UTR (SNP) | VAF 121/354 reads (34%) | catalogued as rs755698995; called by muse, mutect2, varscan2
- ARPC5L | chr9:124868563 C>T | 5'Flank (SNP) | VAF 25/485 reads (5%) | catalogued as rs1230167643; called by muse, mutect2
- ARRDC4 | c.*2569A>C | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- ATG7 | c.2079+19762G>T | Intron (SNP) | VAF 24/289 reads (8%) | called by muse, mutect2
- BX664718.2 | n.860C>T | RNA (SNP) | VAF 41/371 reads (11%) | called by muse, varscan2
- C17orf80 | c.*1287C>A | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- C5orf60 | n.132G>A | RNA (SNP) | VAF 55/518 reads (11%) | called by muse, mutect2, varscan2
- C5orf64 | n.512+52073C>T | Intron (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- C8G | c.*62G>C | 3'UTR (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- CACNA2D2 | chr3:50503583 C>A | 5'Flank (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- CAPRIN2 | c.-615G>A | 5'UTR (SNP) | VAF 124/251 reads (49%) | catalogued as rs1245148384; called by muse, mutect2, varscan2
- CHM | c.315-5498G>A | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*1842C>A | 3'UTR (SNP) | VAF 23/111 reads (21%) | catalogued as rs1385941859; called by muse, mutect2, varscan2
- COP1 | c.-199T>A | 5'UTR (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- CRYGN | c.270+85G>A | Intron (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- DACH1 | chr13:71439284 T>G | 3'Flank (SNP) | VAF 40/74 reads (54%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.*2168G>T | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- DHCR24 | c.1398-122G>A | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- DNM3 | c.1911+1566G>A | Intron (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- EDNRB | c.*1259G>A | 3'UTR (SNP) | VAF 10/52 reads (19%) | called by muse, varscan2
- ERCC6L2 | c.*941C>G | 3'UTR (SNP) | VAF 73/310 reads (24%) | called by muse, mutect2, varscan2
- FOXF1 | c.*692G>A | 3'UTR (SNP) | VAF 47/114 reads (41%) | catalogued as rs1030096906; called by muse, mutect2, varscan2
- FRMPD4 | c.*749C>A | 3'UTR (SNP) | VAF 26/253 reads (10%) | called by muse, varscan2
- FSD2 | c.*1366G>A | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- GGNBP2 | c.1366+27_1366+34del | Intron (DEL) | VAF 30/51 reads (59%) | called by mutect2, pindel, varscan2
- GNA11 | c.*66C>T | 3'UTR (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- GPC6 | c.-368G>A | 5'UTR (SNP) | VAF 84/206 reads (41%) | called by muse, mutect2, varscan2
- GPRIN3 | c.*190G>T | 3'UTR (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- GSN | c.2179+29G>A | Intron (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2
- GUF1 | c.*2109A>C | 3'UTR (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- HTR3E | c.389+58_389+59del | Intron (DEL) | VAF 26/45 reads (58%) | called by pindel, varscan2
- IFI16 | c.2085+399C>A | Intron (SNP) | VAF 10/12 reads (83%) | called by muse, mutect2, varscan2
- INHBC | c.*822A>T | 3'UTR (SNP) | VAF 37/121 reads (31%) | called by muse, mutect2, varscan2
- INSYN2A | c.*589A>G | 3'UTR (SNP) | VAF 59/101 reads (58%) | called by muse, mutect2, varscan2
- ITSN1 | c.*7796C>T | 3'UTR (SNP) | VAF 8/108 reads (7%) | catalogued as COSV67252029; called by muse, mutect2
- KANK4 | c.*834dup | 3'UTR (INS) | VAF 26/84 reads (31%) | called by mutect2, varscan2
- KSR1 | c.*1510A>G | 3'UTR (SNP) | VAF 41/167 reads (25%) | catalogued as rs1197883852; called by muse, mutect2, varscan2
- LDLRAD2 | c.*2306G>A | 3'UTR (SNP) | VAF 19/49 reads (39%) | catalogued as rs765553276; called by muse, mutect2, varscan2
- LRRN3 | c.*333A>G | 3'UTR (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- LTB | c.162+60T>G | Intron (SNP) | VAF 44/78 reads (56%) | called by muse, mutect2, varscan2
- MACROD2 | chr20:16053168 A>G | 3'Flank (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- MAGOH3P | n.36C>T | RNA (SNP) | VAF 24/161 reads (15%) | catalogued as rs533475091; called by muse, mutect2, varscan2
- MECP2 | c.*4493G>T | 3'UTR (SNP) | VAF 7/112 reads (6%) | catalogued as rs781854916; called by muse, mutect2
- MEIOC | c.2457+1009T>A | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- MFSD2A | c.*210G>A | 3'UTR (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
- MGAT5 | c.*2269T>C | 3'UTR (SNP) | VAF 63/180 reads (35%) | called by muse, mutect2, varscan2
- MS4A12 | c.*88G>A | 3'UTR (SNP) | VAF 110/173 reads (64%) | catalogued as COSV99189692; called by muse, mutect2, varscan2
- NOX4 | c.*1134A>C | 3'UTR (SNP) | VAF 95/326 reads (29%) | called by muse, mutect2, varscan2
- NPBWR1 | c.-77C>A | 5'UTR (SNP) | VAF 63/69 reads (91%) | called by muse, mutect2, varscan2
- NSMCE3 | c.-68G>A | 5'UTR (SNP) | VAF 21/102 reads (21%) | catalogued as rs1179221051; called by muse, mutect2, varscan2
- PAX1 | c.*316C>A | 3'UTR (SNP) | VAF 79/341 reads (23%) | called by muse, mutect2, varscan2
- PAX1 | c.*880A>T | 3'UTR (SNP) | VAF 34/150 reads (23%) | called by muse, mutect2, varscan2
- PLCB1 | c.384+14A>C | Intron (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- PPP1R1B | c.241+107C>G | Intron (SNP) | VAF 15/92 reads (16%) | catalogued as rs917569908; called by muse, mutect2, varscan2
- RACK1 | c.637-275G>A | Intron (SNP) | VAF 20/316 reads (6%) | called by muse, mutect2
- RAPGEF3 | c.1596+1260G>A | Intron (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- RPL36A-HNRNPH2 | c.301-3929del | Intron (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel, varscan2
- RPL39 | c.3+557T>G | Intron (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2
- RRP12 | c.*177C>A | 3'UTR (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- SCARA3 | c.*220C>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs1246144481; called by muse, mutect2
- SERTM1 | c.*1718C>G | 3'UTR (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- SIGLEC17P | chr19:51167377 A>C | 5'Flank (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- SLC35A3 | c.*1415A>T | 3'UTR (SNP) | VAF 17/36 reads (47%) | catalogued as rs954902634; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145828721 G>T | 3'Flank (SNP) | VAF 32/145 reads (22%) | called by muse, mutect2, varscan2
- SMARCC1 | c.*2139C>T | 3'UTR (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- SNORD116-28 | n.73G>T | RNA (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- ST6GALNAC3 | c.*231G>A | 3'UTR (SNP) | VAF 13/56 reads (23%) | catalogued as rs144689634, COSV100081910; called by muse, mutect2, varscan2
- TENM3 | c.511+102078A>T | Intron (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- TMEM108 | c.1451-3247C>T | Intron (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
- TMX2 | c.*636G>A | 3'UTR (SNP) | VAF 37/240 reads (15%) | catalogued as rs1400381548; called by muse, mutect2, varscan2
- TNNI2 | c.16-60G>C | Intron (SNP) | VAF 8/68 reads (12%) | catalogued as rs1016760425; called by muse, mutect2, varscan2
- TRAK2 | c.-100G>T | 5'UTR (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- TRIM5 | c.*508A>G | 3'UTR (SNP) | VAF 14/69 reads (20%) | catalogued as rs776766128; called by muse, varscan2
- TRIM7 | c.619-673G>A | Intron (SNP) | VAF 43/123 reads (35%) | called by muse, mutect2, varscan2
- TRMT9B | c.*191G>T | 3'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- TRPS1 | c.*1089G>A | 3'UTR (SNP) | VAF 71/78 reads (91%) | called by muse, mutect2, varscan2
- TSHZ3 | c.*900G>A | 3'UTR (SNP) | VAF 63/154 reads (41%) | called by muse, mutect2, varscan2
- TSPEAR | c.1566+2307G>A | Intron (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- UBXN10 | c.*4512C>T | 3'UTR (SNP) | VAF 26/97 reads (27%) | catalogued as rs1483818304; called by muse, mutect2, varscan2
- USP2-AS1 | n.356G>T | RNA (SNP) | VAF 85/415 reads (20%) | called by muse, mutect2, varscan2
- ZFAND6 | c.-17-8803C>G | Intron (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- ZMAT4 | c.*44T>G | 3'UTR (SNP) | VAF 144/171 reads (84%) | called by muse, mutect2, varscan2
